Somatic mutation profile of tumor specimen TARGET-20-PARIHK-03A (aliquot TARGET-20-PARIHK-03A-01D) from TARGET case TARGET-20-PARIHK, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.5 years (3,830 days).
Specimen TARGET-20-PARIHK-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e0fedc3-a0f6-4412-b127-529e3bf7d43f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARIHK-14A (Bone Marrow Normal), aliquot TARGET-20-PARIHK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21210940-bc55-4b27-8a5b-f3a13b15bfad

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 1, 3'UTR 1, Missense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30A | c.3866G>A p.R1289H (on ENST00000611781; = p.R1233H on NM_052997.2) | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs553718030; called by muse, mutect2, varscan2
- THRAP3 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 103/290 reads (36%) | catalogued as COSV63569234; called by muse, mutect2, varscan2
- WT1 | c.1304-2A>T p.X435_splice | Splice Site (SNP) | VAF 50/158 reads (32%) | catalogued as COSV60078533; called by muse, mutect2, varscan2
- PRKDC | c.*197G>C | 3'UTR (SNP) | VAF 105/319 reads (33%) | called by muse, mutect2, varscan2
